Somatic mutation profile of tumor specimen TCGA-17-Z053-01A (aliquot TCGA-17-Z053-01A-01W-0747-08) from TCGA case TCGA-17-Z053, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z053-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 135d87f4-2943-4e79-aaac-0693b2eeeb8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z053-11A (Solid Tissue Normal), aliquot TCGA-17-Z053-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ecdd76a-4131-4abb-a91e-add0e37e7e1a

The open-access MAF lists 267 somatic variants for this specimen: 201 protein-altering or splice-affecting, 62 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 157, Silent 62, Nonsense Mutation 20, Frame Shift Del 11, Splice Site 7, Splice Region 4, Intron 3, Frame Shift Ins 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.7891C>T p.R2631* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as rs587783457, CM109255, COSV71113106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 67/268 reads (25%) | catalogued as rs63751326, CM055996, COSV51878399; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 54/139 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABAT | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs879047139; called by muse, mutect2, varscan2
- AC136428.1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs768485072, COSV101434983; called by mutect2, varscan2
- ACSF3 | c.1135G>C p.G379R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58081081; called by muse, mutect2, varscan2
- ANO3 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs756025616, COSV56781984, COSV56808852; called by muse, mutect2, varscan2
- AP002512.3 | c.994C>G p.R332G | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV99687990; called by muse, mutect2
- C9 | c.1677del p.K559Nfs*44 | Frame Shift Del (DEL) | VAF 51/307 reads (17%) | catalogued as rs762159491; called by mutect2, pindel, varscan2
- CACNA1G | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184328705; called by mutect2, varscan2
- CCDC85A | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV68156638; called by mutect2, varscan2
- CDC42BPB | c.2597G>T p.R866L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV100775619; called by muse, mutect2, varscan2
- CDC5L | c.1239C>T p.F413= | Splice Region (SNP) | VAF 14/364 reads (4%) | catalogued as COSV65175369, COSV65176385; called by muse, mutect2
- CDH17 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV50325454; called by muse, mutect2
- CHRNE | c.632C>A p.P211Q | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773916039; called by muse, mutect2, varscan2
- CPN2 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV60470510; called by muse, mutect2, varscan2
- CTNND2 | c.1559del p.G520Afs*36 | Frame Shift Del (DEL) | VAF 40/273 reads (15%) | catalogued as COSV58930767; called by mutect2, varscan2
- DHX36 | c.1606-2A>G p.X536_splice | Splice Site (SNP) | VAF 22/125 reads (18%) | catalogued as COSV100273579; called by muse, varscan2
- DMD | c.1953G>C p.W651C | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55876591; called by muse, mutect2, varscan2
- EPX | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563964992, COSV56599574; called by muse, mutect2, varscan2
- ERICH3 | c.2841G>C p.E947D | Missense Mutation (SNP) | VAF 78/708 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.559); catalogued as COSV100444964; called by muse, mutect2, varscan2
- FANCM | c.2618G>A p.G873D | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs766902093, COSV99951365; called by muse, mutect2, varscan2
- FIGN | c.448A>C p.S150R | Missense Mutation (SNP) | VAF 56/380 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV60769156; called by muse, varscan2
- FN3KRP | c.561G>T p.R187S | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV53931461; called by muse, mutect2, varscan2
- GP1BA | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs748102207; called by muse, mutect2, varscan2
- GP2 | c.1556-1G>T p.X519_splice (on ENST00000381362 / NM_001007240.3; = p.X516_splice on NM_001502.4) | Splice Site (SNP) | VAF 85/441 reads (19%) | catalogued as COSV100221441, COSV56895297; called by muse, mutect2, varscan2
- GRIA3 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52057735; called by muse, mutect2, varscan2
- GRIN2A | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 44/584 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs560057284, COSV58020945, COSV58030818; ClinVar: uncertain significance / benign; called by muse, mutect2
- H2AC16 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.791); catalogued as rs184589037, COSV58899169; called by muse, mutect2
- HEATR5B | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99248440; called by muse, mutect2, varscan2
- HPSE | c.659G>T p.W220L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60988963; called by mutect2, varscan2
- IL17A | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as rs767872393; called by muse, mutect2, varscan2
- KCNH2 | c.2504G>T p.R835L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as CM148552, COSV100060207, COSV51126119; called by muse, mutect2, varscan2
- KCNU1 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1375829484, COSV101298918; called by muse, mutect2
- KRTAP10-10 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 34/187 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs782075173; called by muse, mutect2, varscan2
- LRP1B | c.11320T>A p.C3774S | Missense Mutation (SNP) | VAF 97/429 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101257743; called by muse, mutect2, varscan2
- LTBP1 | c.4523G>C p.R1508P (on ENST00000404816 / NM_206943.4; = p.R1182P on NM_000627.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV55379621; called by muse, mutect2, varscan2
- LYZL2 | c.260G>T p.G87V (on ENST00000375318; = p.G41V on NM_183058.3) | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150609822; called by muse, mutect2, varscan2
- MAP3K15 | c.3294C>A p.A1098= | Splice Region (SNP) | VAF 53/79 reads (67%) | catalogued as rs140041575, COSV100135951; called by muse, mutect2, varscan2
- MAP7D3 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1282582121, COSV60172734; called by muse, mutect2, varscan2
- MS4A6A | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV60619382; called by muse, mutect2, varscan2
- MYEOV | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as rs371601493; called by muse, mutect2, varscan2
- NADK | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1364344087; called by muse, mutect2, varscan2
- NLRP14 | c.2523C>G p.S841R | Missense Mutation (SNP) | VAF 49/380 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs1485823531; called by muse, mutect2, varscan2
- NPY | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs1404377443; called by muse, mutect2
- NUP210 | c.5455G>A p.A1819T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54409015; called by muse, mutect2, varscan2
- OR10AG1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV56632669, COSV56635181; called by muse, mutect2
- OR1I1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV52918977; called by muse, mutect2
- PCDHGA7 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99541156; called by muse, mutect2, varscan2
- PHF14 | c.820A>T p.K274* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV68857281; called by muse, mutect2, varscan2
- PI4KB | c.158A>T p.Q53L (on ENST00000368873 / NM_001369623.1; = p.Q65L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV55015358; called by muse, mutect2, varscan2
- POU3F4 | c.293C>A p.S98* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as CM098352; called by muse, mutect2
- PROCA1 | c.493C>T p.H165Y (on ENST00000439862 / NM_001366301.1; = p.H137Y on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.222); catalogued as rs748342765; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1592G>A p.R531K | Missense Mutation (SNP) | VAF 106/373 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs753123284, COSV54764594; called by muse, mutect2, varscan2
- RARG | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs1051888927; called by muse, mutect2
- RNF175 | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.171); catalogued as COSV99924277; called by muse, mutect2, varscan2
- RPS6KA2 | c.1759G>T p.G587C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99692463; called by muse, mutect2, varscan2
- RYR2 | c.13840G>T p.G4614W | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936573890, COSV100769562, COSV63672474; called by muse, mutect2, varscan2
- SBSN | c.1598G>A p.G533E (on ENST00000452271 / NM_001166034.2; = p.G190E on NM_198538.4) | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV104437990; called by muse, mutect2, varscan2
- SEC23A | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100305883; called by muse, mutect2, varscan2
- SEMA6D | c.2713C>G p.Q905E (on ENST00000316364 / NM_153618.2; = p.Q843E on NM_020858.2) | Missense Mutation (SNP) | VAF 76/383 reads (20%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.599); catalogued as COSV100317658, COSV60376169; called by muse, mutect2, varscan2
- SETBP1 | c.4766G>A p.G1589E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as rs1436777220; called by muse, mutect2, varscan2
- SIGLEC5 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as rs1441967002, COSV55784646; called by muse, mutect2, varscan2
- SLC7A14 | c.913G>A p.V305M | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as rs372221406, COSV51592714; called by muse, mutect2, varscan2
- SPCS1 | c.460G>C p.D154H (on ENST00000233025; = p.D87H on NM_014041.5) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99236779; called by muse, mutect2, varscan2
- SRCAP | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.1); catalogued as COSV52676971; called by muse, mutect2
- SRD5A2 | c.464T>C p.L155S | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.292); catalogued as CD110902; called by muse, mutect2, varscan2
- ST7 | c.1228G>T p.V410L (on ENST00000265437 / NM_021908.3; = p.V387L on NM_018412.4) | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55380635; called by muse, mutect2, varscan2
- STAC | c.831+1G>T p.X277_splice | Splice Site (SNP) | VAF 82/242 reads (34%) | catalogued as rs1036208393, COSV56216077; called by muse, mutect2, varscan2
- STAG2 | c.3613C>T p.R1205* | Nonsense Mutation (SNP) | VAF 24/138 reads (17%) | catalogued as rs867285087, COSV54355049; called by muse, mutect2, varscan2
- TNC | c.1168G>T p.G390W | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100406365; called by muse, mutect2, varscan2
- VPS39 | c.866C>T p.S289L (on ENST00000348544 / NM_001301138.2; = p.S278L on NM_015289.5) | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs760629334, COSV100528966; called by muse, mutect2, varscan2
- ZBTB5 | c.419T>C p.M140T | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1382492005; called by muse, mutect2, varscan2
- ZNF710 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs748861157, COSV51564317; called by muse, mutect2, varscan2
- ZNF91 | c.946C>G p.H316D | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100321856; called by muse, mutect2, varscan2
- ADAM29 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 32/280 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by mutect2, varscan2
- ADAM30 | c.2059T>A p.W687R | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM7 | c.1409_1410del p.P470Rfs*12 | Frame Shift Del (DEL) | VAF 17/108 reads (16%) | called by mutect2, pindel
- ADGRB3 | c.3872G>T p.G1291V | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANK2 | c.3559del p.A1187Hfs*8 | Frame Shift Del (DEL) | VAF 21/213 reads (10%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.2507T>C p.L836S (on ENST00000611781; = p.L780S on NM_052997.2) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.245); called by mutect2, varscan2
- AP1B1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGAP15 | c.280G>T p.G94* | Nonsense Mutation (SNP) | VAF 57/246 reads (23%) | called by muse, mutect2, varscan2
- ARHGEF19 | c.2101C>G p.P701A | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2
- ARID5B | c.3567G>C p.*1189Yext*38 | Nonstop Mutation (SNP) | VAF 35/178 reads (20%) | called by muse, mutect2, varscan2
- ATF2 | c.200-1G>T p.X67_splice | Splice Site (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- ATRNL1 | c.2159C>A p.T720N | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BBS7 | c.410A>G p.D137G | Missense Mutation (SNP) | VAF 78/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BCHE | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- BEND4 | c.608A>T p.Q203L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BMP1 | c.472T>G p.W158G | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTBD16 | c.397A>T p.K133* | Nonsense Mutation (SNP) | VAF 30/174 reads (17%) | called by muse, mutect2, varscan2
- BZW2 | c.1034A>T p.K345M | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- C4orf17 | c.549C>A p.I183= | Splice Region (SNP) | VAF 12/257 reads (5%) | called by muse, mutect2
- CACNB2 | c.290G>T p.R97I (on ENST00000324631 / NM_201596.3; = p.R42I on NM_000724.4) | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CADPS2 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC136 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC151 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- CCDC170 | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CCDC190 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- CCT6A | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD2 | c.2174A>C p.Q725P | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4M | c.45G>A p.L15= | Splice Region (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
- CLIP1 | c.494C>G p.S165* | Nonsense Mutation (SNP) | VAF 32/278 reads (12%) | called by muse, varscan2
- COL14A1 | c.1286C>A p.T429N | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- CSMD3 | c.577A>T p.R193* | Nonsense Mutation (SNP) | VAF 70/296 reads (24%) | called by muse, mutect2, varscan2
- CYP17A1 | c.621C>A p.D207E | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CYP1A2 | c.1132C>A p.H378N | Missense Mutation (SNP) | VAF 34/501 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2
- CYP21A2 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 28/220 reads (13%) | called by muse, mutect2, varscan2
- DAAM2 | c.824C>A p.T275K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- DACH2 | c.1726C>A p.P576T | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DNAJB14 | c.867G>T p.M289I | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNM1L | c.788_800del p.R263Lfs*23 | Frame Shift Del (DEL) | VAF 41/159 reads (26%) | called by mutect2, pindel, varscan2
- DQX1 | c.2096C>G p.T699R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EIF4G3 | c.2945G>T p.C982F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, varscan2
- EMC3 | c.520del p.L174Sfs*12 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, varscan2
- ERICH3 | c.444+1G>A p.X148_splice | Splice Site (SNP) | VAF 143/639 reads (22%) | called by muse, mutect2, varscan2
- ETAA1 | c.2456C>A p.S819* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- EYS | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FABP12 | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 52/331 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, varscan2
- FAM135B | c.3150G>T p.E1050D | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM135B | c.2121del p.L707Ffs*22 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | called by mutect2, pindel, varscan2
- FER1L6 | c.5290-1G>A p.X1764_splice | Splice Site (SNP) | VAF 16/84 reads (19%) | called by mutect2, varscan2
- FIBP | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- FIG4 | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 69/324 reads (21%) | called by muse, mutect2, varscan2
- G3BP2 | c.398A>T p.Y133F | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GBP5 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GFPT2 | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GHSR | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by mutect2, varscan2
- GNPTAB | c.3234C>G p.Y1078* | Nonsense Mutation (SNP) | VAF 61/249 reads (24%) | called by muse, mutect2, varscan2
- GPR155 | c.1811G>T p.C604F | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRM7 | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 60/128 reads (47%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HAS1 | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCLS1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- HIP1 | c.1667T>C p.L556P | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- IGFN1 | c.1849G>C p.D617H (on ENST00000295591 / NM_001367841.1; = p.D3074H on NM_001164586.2) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV2-5 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGKV3D-11 | c.47del p.P16Qfs*9 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, varscan2
- IRX3 | c.1451+1G>T p.X484_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- ITGA6 | c.1586G>A p.G529E (on ENST00000442250; = p.G490E on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/399 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.018); called by muse, mutect2
- ITIH2 | c.2272T>A p.Y758N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITM2A | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- KALRN | c.5480del p.G1827Vfs*17 (on ENST00000360013 / NM_001024660.4; = p.G130Vfs*17 on NM_007064.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | called by mutect2, pindel, varscan2
- KIF13A | c.2560G>C p.E854Q | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- KRTAP21-1 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 81/329 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- MAGEB4 | c.587C>A p.P196Q | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARK3 | c.1886A>T p.Y629F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- MATN2 | c.1532C>G p.P511R | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- MFSD8 | c.805G>C p.V269L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- MRPL15 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH6 | c.3371T>A p.L1124Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO18B | c.2430G>A p.M810I | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, varscan2
- MYOT | c.410C>A p.A137E | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.89); PolyPhen benign (0.088); called by muse, mutect2
- NLRP14 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- NRP1 | c.2605G>C p.V869L | Missense Mutation (SNP) | VAF 107/318 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OPRK1 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- OR52N5 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.192); called by muse, varscan2
- OR6C76 | c.812del p.V271Efs*12 | Frame Shift Del (DEL) | VAF 35/200 reads (18%) | called by mutect2, pindel, varscan2
- PCDH7 | c.3029A>T p.Q1010L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by mutect2, varscan2
- PCDHB14 | c.1192A>C p.K398Q | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PEG3 | c.466T>C p.S156P | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, varscan2
- PLAUR | c.991A>G p.T331A | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PROS1 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRH | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- RANBP6 | c.167C>A p.A56D | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- RASA1 | c.2912del p.L971* | Frame Shift Del (DEL) | VAF 64/274 reads (23%) | called by mutect2, pindel, varscan2
- RGS22 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 120/709 reads (17%) | called by muse, mutect2, varscan2
- RICTOR | c.4670A>G p.Q1557R | Missense Mutation (SNP) | VAF 48/366 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RIMS1 | c.4957A>T p.I1653F | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- RTN1 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 85/275 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAGE1 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 70/159 reads (44%) | called by muse, mutect2, varscan2
- SERPINE1 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, varscan2
- SERPINE1 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 96/375 reads (26%) | called by muse, varscan2
- SI | c.3533A>C p.Q1178P | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- SLC17A2 | c.1213T>C p.Y405H (on ENST00000265425; = p.D355= on NM_005835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC23A2 | c.866A>C p.N289T | Missense Mutation (SNP) | VAF 131/325 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- SLC6A5 | c.1235C>A p.A412D | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.555); called by muse, mutect2
- SMC6 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SPEF2 | c.2349A>T p.L783F | Missense Mutation (SNP) | VAF 59/312 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPEG | c.7768C>T p.L2590F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ST18 | c.2766T>A p.S922R | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.074); called by mutect2, varscan2
- SVEP1 | c.9960C>A p.N3320K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE1 | c.14174G>A p.G4725D (on ENST00000367255 / NM_182961.4; = p.G4654D on NM_033071.3) | Missense Mutation (SNP) | VAF 154/237 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SYTL5 | c.2070C>A p.N690K | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM1 | c.7654G>A p.A2552T | Missense Mutation (SNP) | VAF 96/193 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TMEM40 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV19 | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRDN | c.2030T>C p.V677A | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TRIM21 | c.1195C>A p.H399N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TRIM44 | c.849C>G p.I283M | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- TRRAP | c.10847A>G p.Y3616C (on ENST00000359863 / NM_001244580.1; = p.Y3587C on NM_003496.3) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSSK3 | c.653T>C p.M218T | Missense Mutation (SNP) | VAF 82/296 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TTN | c.10020G>A p.M3340I (on ENST00000591111; = p.M3294I on NM_003319.4) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | PolyPhen benign (0.013); called by muse, mutect2
- TYRO3 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR6 | c.611dup p.I205Nfs*82 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | called by pindel, varscan2
- ZC4H2 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF234 | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 46/230 reads (20%) | called by mutect2, varscan2
- ZNF329 | c.1479G>T p.K493N | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF564 | c.185T>A p.I62N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ZNF772 | c.982G>T p.G328W | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF831 | c.3445G>C p.E1149Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ABAT | c.1203G>T p.R401= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV99190885, COSV99190966; called by muse, mutect2, varscan2
- ABHD11 | c.841C>A p.R281= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV56106142; called by muse, mutect2
- ADARB1 | c.1125A>G p.T375= | Silent (SNP) | VAF 23/147 reads (16%) | called by muse, mutect2, varscan2
- ADAT2 | c.330T>C p.C110= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2
- AMPD1 | c.1335G>A p.A445= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs141829342; called by muse, mutect2, varscan2
- ANKMY1 | c.1314G>T p.V438= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- APC | c.3603A>G p.S1201= | Silent (SNP) | VAF 80/260 reads (31%) | catalogued as rs760339669; ClinVar: likely benign; called by muse, mutect2, varscan2
- APOBR | c.1752G>A p.L584= (on ENST00000431282; = p.L593= on NM_018690.4) | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- BRPF3 | c.693C>T p.F231= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as rs142038497; called by muse, mutect2, varscan2
- CCDC8 | c.717G>C p.A239= | Silent (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- CDH17 | c.1671G>A p.V557= | Silent (SNP) | VAF 12/296 reads (4%) | called by muse, mutect2
- CLEC14A | c.1182C>A p.S394= | Silent (SNP) | VAF 12/62 reads (19%) | called by mutect2, varscan2
- COL4A3 | c.1764G>C p.L588= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV67421762; called by muse, mutect2, varscan2
- CREBBP | c.6270C>G p.L2090= | Silent (SNP) | VAF 46/121 reads (38%) | called by muse, mutect2, varscan2
- CTNNA2 | c.609G>T p.R203= | Silent (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- CYP7A1 | c.1128C>T p.D376= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as rs1469727504; called by muse, mutect2
- DCAF4L2 | c.1071C>G p.P357= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs762077763, COSV60476760, COSV60478009; called by muse, mutect2, varscan2
- DNAH8 | c.11073C>G p.L3691= | Silent (SNP) | VAF 47/175 reads (27%) | catalogued as COSV59423801; called by muse, mutect2, varscan2
- DSCAML1 | c.2301T>C p.G767= (on ENST00000321322; = p.G707= on NM_020693.4) | Silent (SNP) | VAF 40/126 reads (32%) | called by muse, mutect2, varscan2
- DSG4 | c.2247C>T p.A749= | Silent (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- ERVW-1 | c.690C>A p.T230= | Silent (SNP) | VAF 58/298 reads (19%) | called by muse, mutect2, varscan2
- F13A1 | c.1474A>C p.R492= | Silent (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- FABP12 | c.201G>T p.L67= | Silent (SNP) | VAF 54/336 reads (16%) | called by muse, varscan2
- FAT3 | c.2310G>T p.T770= | Silent (SNP) | VAF 30/275 reads (11%) | catalogued as COSV53146211; called by muse, mutect2, varscan2
- FNDC1 | c.1836G>T p.A612= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs761593972, COSV51937145; called by muse, mutect2, varscan2
- GIMAP5 | c.532C>A p.R178= | Silent (SNP) | VAF 106/474 reads (22%) | called by muse, varscan2
- GRIK1 | c.348C>G p.V116= | Silent (SNP) | VAF 35/258 reads (14%) | called by muse, mutect2, varscan2
- HECW2 | c.1431T>C p.G477= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2, varscan2
- HMGB2 | c.261G>C p.G87= | Silent (SNP) | VAF 85/292 reads (29%) | catalogued as COSV56633673; called by muse, mutect2, varscan2
- IGDCC4 | c.2274G>A p.A758= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as rs745801357, COSV61536726; called by muse, mutect2, varscan2
- JHY | c.2265G>T p.L755= | Silent (SNP) | VAF 32/177 reads (18%) | called by muse, varscan2
- MTOR | c.57G>T p.V19= | Silent (SNP) | VAF 34/143 reads (24%) | called by muse, mutect2, varscan2
- MYO1D | c.759C>T p.A253= | Silent (SNP) | VAF 32/383 reads (8%) | called by muse, mutect2
- NPR2 | c.615A>G p.R205= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- NXNL1 | c.9C>T p.S3= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- OR10G9 | c.546C>A p.P182= | Silent (SNP) | VAF 86/578 reads (15%) | called by muse, varscan2
- OR2T6 | c.564C>A p.A188= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV100861634; called by muse, mutect2, varscan2
- OR51D1 | c.228G>C p.L76= | Silent (SNP) | VAF 136/408 reads (33%) | called by muse, varscan2
- OR6C4 | c.501T>C p.C167= | Silent (SNP) | VAF 126/389 reads (32%) | catalogued as rs757027890; called by muse, mutect2, varscan2
- OR8B4 | c.45G>T p.V15= | Silent (SNP) | VAF 24/150 reads (16%) | called by muse, mutect2, varscan2
- PHKA1 | c.2310G>A p.L770= | Silent (SNP) | VAF 120/486 reads (25%) | called by muse, mutect2, varscan2
- PIK3R4 | c.2073C>G p.V691= | Silent (SNP) | VAF 48/469 reads (10%) | catalogued as rs751976795; called by muse, mutect2, varscan2
- POTEF | c.2736C>A p.I912= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.243G>T p.V81= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as COSV100742910; called by muse, mutect2, varscan2
- PRSS1 | c.414G>A p.K138= | Silent (SNP) | VAF 48/272 reads (18%) | catalogued as rs749482440; called by mutect2, varscan2
- PTPN21 | c.1863C>T p.S621= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs766228339, COSV100161870; called by muse, mutect2, varscan2
- RAI14 | c.375T>C p.Y125= | Silent (SNP) | VAF 49/798 reads (6%) | catalogued as rs780977153; called by muse, mutect2
- RASGRP4 | c.1477C>A p.R493= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV53039900, COSV99384963; called by muse, mutect2, varscan2
- RIMS1 | c.4956G>A p.V1652= | Silent (SNP) | VAF 69/328 reads (21%) | catalogued as COSV53452988; called by muse, mutect2, varscan2
- SCG2 | c.624G>T p.L208= | Silent (SNP) | VAF 90/606 reads (15%) | catalogued as COSV59540518; called by mutect2, varscan2
- SEMA3D | c.1305A>T p.A435= | Silent (SNP) | VAF 123/533 reads (23%) | called by muse, mutect2, varscan2
- SEMA4G | c.519C>T p.G173= | Silent (SNP) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- SGCD | c.753G>C p.T251= (on ENST00000435422 / NM_001128209.2; = p.T252= on NM_000337.5) | Silent (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- SHKBP1 | c.1905C>A p.A635= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- SIGLEC1 | c.5067G>T p.T1689= | Silent (SNP) | VAF 22/128 reads (17%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2139T>C p.H713= (on ENST00000540229 / NM_001371097.1; = p.H652= on NM_001009562.4) | Silent (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- TAF1L | c.1806C>A p.T602= | Silent (SNP) | VAF 67/490 reads (14%) | catalogued as COSV54259956, COSV54265989; called by muse, mutect2, varscan2
- TBC1D32 | c.2118T>C p.C706= | Silent (SNP) | VAF 37/181 reads (20%) | called by muse, mutect2, varscan2
- TICRR | c.1533G>A p.E511= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as rs1333286704; called by muse, mutect2, varscan2
- TRAPPC1 | c.429G>T p.R143= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.12003T>C p.S4001= (on ENST00000591111; = p.S3955= on NM_003319.4) | Silent (SNP) | VAF 125/374 reads (33%) | called by muse, mutect2, varscan2
- ZNF354A | c.1818G>A p.*606= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs1169948774; called by muse, varscan2
- AL132655.6 | chr20:58840256 C>T | 5'Flank (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- H2BP2 | n.1062-358A>T | Intron (SNP) | VAF 172/400 reads (43%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-2217G>A | Intron (SNP) | VAF 24/86 reads (28%) | called by muse, varscan2
- TTN | c.10360+4155T>A | Intron (SNP) | VAF 60/224 reads (27%) | catalogued as rs749996737; called by muse, mutect2, varscan2
